Somatic mutation profile of tumor specimen TCGA-VP-A879-01A (aliquot TCGA-VP-A879-01A-11D-A34U-08) from TCGA case TCGA-VP-A879, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.6 years (25,799 days).
Specimen TCGA-VP-A879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0adabe9-255a-4c56-b858-ef8549247861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A879-10A (Blood Derived Normal), aliquot TCGA-VP-A879-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3aded36-edb8-4edf-aa63-186419150ae9

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 30, Silent 6, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6162C>A p.N2054K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV101330129; called by mutect2, varscan2
- ASXL2 | c.3076A>C p.S1026R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99711730; called by muse, mutect2
- CACNA1E | c.4048C>T p.R1350C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1251838491, COSV100704333; called by muse, mutect2
- CDC16 | c.1325A>G p.D442G | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV99373064; called by muse, mutect2
- COBL | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs374580746; called by muse, mutect2, varscan2
- CYLC2 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs188765977, COSV66336036; called by muse, mutect2, varscan2
- EDF1 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99808199; called by muse, mutect2, varscan2
- FOXR2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as COSV100189464; called by muse, mutect2
- GSTA3 | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99274621; called by muse, mutect2, varscan2
- H3C2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.217); catalogued as COSV52520191, COSV99451646; called by muse, mutect2
- LPIN1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124543, CM123013, COSV99876982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.12710G>T p.C4237F | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101258952; called by muse, mutect2
- MCF2L | c.2113G>T p.D705Y (on ENST00000375608; = p.D673Y on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99996026; called by muse, mutect2
- MYH10 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52595762; called by muse, mutect2, varscan2
- OR2D2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs770036166, COSV55057528; called by muse, mutect2, varscan2
- PCDHB9 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV53376035; called by muse, mutect2, varscan2
- PEAK1 | c.3772C>T p.R1258C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.642); catalogued as rs776197799, COSV56936661; called by muse, mutect2
- PGLYRP2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV52994897, COSV99484204; called by muse, mutect2
- PKD1L1 | c.1624T>G p.F542V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99220862; called by muse, mutect2, varscan2
- PTPRD | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 12/131 reads (9%) | catalogued as COSV100643335, COSV100645960; called by muse, mutect2, varscan2
- RYR3 | c.11683G>T p.V3895F (on ENST00000389232; = p.V3896F on NM_001036.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213465; called by muse, mutect2, varscan2
- SLAMF6 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.151); catalogued as COSV100924915, COSV63588305; called by muse, mutect2, varscan2
- SLCO6A1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs547449839, COSV101133668, COSV101134284; called by muse, mutect2, varscan2
- SLITRK5 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV100281038; called by muse, varscan2
- TARBP1 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs201389692; called by muse, mutect2, varscan2
- TG | c.6747G>C p.L2249F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.022); catalogued as COSV55063719, COSV99602304; called by muse, mutect2, varscan2
- THSD4 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 93/426 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs374464107; called by muse, mutect2, varscan2
- TIA1 | c.1136G>A p.R379Q (on ENST00000433529 / NM_001351511.1; = p.R368Q on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.101); catalogued as rs774014016, COSV99248878; called by muse, mutect2, varscan2
- UNC13D | c.2474C>T p.T825I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.065); catalogued as rs1427228570, COSV99257193; called by muse, mutect2, varscan2
- XPO4 | c.2270T>C p.L757S | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1353449370, COSV99688990; called by muse, mutect2
- YEATS2 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100528141; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1954_1957delinsT p.Q652_N653delinsY | In Frame Del (DEL) | VAF 22/91 reads (24%) | called by pindel, varscan2*
- SLC30A9 | c.450del p.R151Efs*19 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- ASAP3 | c.186C>T p.I62= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100369564; called by muse, mutect2, varscan2
- C1QC | c.282G>A p.G94= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV65889445; called by muse, mutect2, varscan2
- IGKV3-11 | c.258G>A p.G86= | Silent (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1008T>C p.D336= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as rs1258326589, COSV100177845; called by muse, mutect2, varscan2
- PTPRH | c.1278C>T p.D426= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs139891947; called by muse, mutect2, varscan2
- SNAP91 | c.2173T>C p.L725= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99536106; called by muse, mutect2, varscan2
